Somatic mutation profile of tumor specimen BA2377D (aliquot aq-BA2377D) from BEATAML1.0 case 2385, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with t(9;11)(p22;q23), MLLT3-MLL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 35.2 years (12,860 days).
Specimen BA2377D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8703899d-06fa-4292-9fd5-78738447eef1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2126D (Solid Tissue Normal), aliquot aq-BA2126D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f063dc84-c1ec-48e6-a246-29608ed2808c

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, In Frame Del 1, RNA 1, 3'UTR 1, In Frame Ins 1, Intron 1, 3'Flank 1, 5'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OVGP1 | c.1606A>G p.S536G | Missense Mutation (SNP) | VAF 26/79 reads (33%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs3767609, COSV63857328; ClinVar: benign; called by muse, varscan2
- ADAMTS7 | c.2708G>A p.R903Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs774523736; called by muse, varscan2
- ARHGEF10L | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs140059332, COSV63417329; called by muse, mutect2, varscan2
- EFCAB8 | c.3394-1G>T p.X1132_splice | Splice Site (SNP) | VAF 41/78 reads (53%) | catalogued as COSV71955240; called by muse, mutect2, varscan2
- MYO7B | c.5179G>A p.E1727K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs778564583; called by muse, mutect2, varscan2
- SEPTIN4 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420562181; called by muse, mutect2, varscan2
- TCHH | c.1072_1074del p.E358del | In Frame Del (DEL) | VAF 27/205 reads (13%) | catalogued as rs751166610; called by mutect2*, varscan2
- TYR | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 109/223 reads (49%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs561008244, COSV54479660; called by muse, mutect2, varscan2
- AMOTL2 | c.815C>G p.P272R | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.034); called by muse, varscan2
- ASPHD1 | c.102C>A p.S34R | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- ASXL1 | c.2826_2832del p.D943Qfs*6 | Frame Shift Del (DEL) | VAF 112/242 reads (46%) | called by mutect2, pindel, varscan2
- EFL1 | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- FLT3 | c.1323_1328dup p.L442_A443dup | In Frame Ins (INS) | VAF 42/113 reads (37%) | called by mutect2, pindel, varscan2
- FUT6 | c.949A>C p.S317R | Missense Mutation (SNP) | VAF 152/368 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAU | c.354C>T p.N118= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs1258654705, COSV54194804; called by muse, mutect2, varscan2
- GOLGA8O | c.507C>T p.R169= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs778644601; called by muse, varscan2
- MAP7 | c.564G>A p.S188= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs759368260, COSV63417050; called by muse, mutect2, varscan2
- PPL | c.933C>T p.C311= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as rs757389593, COSV62046058; called by muse, mutect2, varscan2
- TTN | c.6210A>G p.E2070= (on ENST00000591111; = p.E2024= on NM_003319.4) | Silent (SNP) | VAF 138/291 reads (47%) | called by muse, mutect2, varscan2
- COL6A5 | c.*6C>T | 3'UTR (SNP) | VAF 63/140 reads (45%) | catalogued as rs1031418529; called by muse, mutect2, varscan2
- IL12RB1 | c.-53C>T | 5'UTR (SNP) | VAF 56/126 reads (44%) | catalogued as rs769260611, COSV100443025; called by muse, mutect2, varscan2
- NOC2LP2 | n.537C>T | RNA (SNP) | VAF 209/479 reads (44%) | catalogued as rs755942394; called by muse, mutect2, varscan2
- TANC2 | c.3676+607C>T | Intron (SNP) | VAF 24/79 reads (30%) | called by muse, varscan2
- ZSWIM4 | chr19:13836402 A>C | 3'Flank (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
